Somatic mutation profile of tumor specimen TCGA-ED-A4XI-01A (aliquot TCGA-ED-A4XI-01A-11D-A25V-10) from TCGA case TCGA-ED-A4XI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.9 years (21,497 days).
Specimen TCGA-ED-A4XI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff472786-a3c2-4811-85f2-c91df6fe3cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A4XI-10A (Blood Derived Normal), aliquot TCGA-ED-A4XI-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3408e372-6a09-4abf-89f2-898207707fef

The open-access MAF lists 154 somatic variants for this specimen: 119 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 24, Intron 6, Nonsense Mutation 6, Splice Site 5, 5'UTR 2, Frame Shift Del 2, 3'UTR 1, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK8 | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53756907; called by muse, mutect2
- AKAP3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV57418032; called by muse, mutect2, varscan2
- APEH | c.1751T>C p.M584T | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs1421898924, COSV56534960; called by muse, mutect2, varscan2
- ARFGEF3 | c.3974-1G>C p.X1325_splice | Splice Site (SNP) | VAF 9/149 reads (6%) | catalogued as COSV52462195; called by muse, mutect2
- ARHGAP5 | c.3504T>A p.Y1168* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | catalogued as COSV61537330; called by muse, mutect2
- ARHGEF15 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1446881098, COSV62725704; called by muse, varscan2
- BAP1 | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56230932, COSV56232984; called by muse, mutect2, varscan2
- BMP2K | c.2050A>G p.I684V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.012); catalogued as COSV55010498; called by muse, mutect2, varscan2
- BSN | c.1349A>G p.K450R | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99610160; called by muse, mutect2
- C11orf95 | c.1853A>G p.K618R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV58029984; called by muse, mutect2, varscan2
- C6orf15 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | catalogued as COSV52538885; called by muse, mutect2, varscan2
- CAMP | c.329G>A p.R110Q (on ENST00000296435; = p.R107Q on NM_004345.5) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs375338469; called by muse, mutect2, varscan2
- CAMTA2 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs765389294, COSV61835926; called by muse, mutect2, varscan2
- CCDC168 | c.6173A>T p.Y2058F | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV70555475; called by muse, mutect2
- CCL13 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.07); catalogued as COSV56774990; called by muse, mutect2
- CCR6 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV59475540; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2855A>G p.Y952C | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62575740; called by muse, mutect2, varscan2
- CFAP58 | c.2252T>G p.L751R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV63834900; called by muse, mutect2, varscan2
- CHSY3 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280763; called by muse, mutect2, varscan2
- CISH | c.483G>T p.Q161H (on ENST00000348721 / NM_145071.4; = p.Q178H on NM_013324.6) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV62295113; called by muse, mutect2
- CLDN1 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV55044438; called by muse, mutect2
- COL11A1 | c.4130A>G p.K1377R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100618354; called by muse, mutect2
- CSMD3 | c.6991G>C p.E2331Q (on ENST00000297405 / NM_001363185.1; = p.E2227Q on NM_052900.3) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52109234, COSV52230881; called by mutect2, varscan2
- CSRP3 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs377066670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSTB | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV52367091; called by muse, mutect2
- CYBRD1 | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs777956355, COSV58427071; called by muse, mutect2, varscan2
- DDX50 | c.1103A>T p.Q368L | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV65292755; called by muse, mutect2, varscan2
- DENND4A | c.2324G>T p.C775F | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71266443; called by muse, mutect2
- DNAH6 | c.7450G>A p.E2484K | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52869199; called by muse, mutect2
- EPHB2 | c.2044G>A p.V682I (on ENST00000400191 / NM_001309193.2; = p.V683I on NM_004442.7) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs779022970, COSV65859911; called by muse, mutect2, varscan2
- EPHB3 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as COSV57807305; called by muse, mutect2
- ERAP2 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV65940302; called by muse, mutect2, varscan2
- FANCL | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs1170759423, COSV99288089; called by muse, mutect2
- FASTKD1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs150915965, COSV70007141; called by muse, mutect2, varscan2
- FER1L5 | c.130T>A p.W44R | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69680694; called by muse, mutect2
- FLG | c.5431G>T p.D1811Y | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64240859, COSV64244065; called by muse, mutect2, varscan2
- GBP2 | c.1274T>A p.F425Y | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV65069823; called by muse, mutect2, varscan2
- GEMIN5 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53562102; called by muse, mutect2, varscan2
- HSPA9 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51865176; called by muse, mutect2, varscan2
- HTT | c.8960T>A p.F2987Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV61864931; called by muse, mutect2
- IGSF9B | c.1587G>A p.W529* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV58069717; called by muse, mutect2, varscan2
- IQSEC3 | c.2264T>C p.I755T (on ENST00000538872 / NM_001170738.2; = p.I452T on NM_015232.1) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV58286955; called by muse, mutect2, varscan2
- ITGAE | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs772032855, COSV53996404; called by muse, mutect2, varscan2
- KCNH6 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs749594163, COSV59005008; called by muse, mutect2
- KDM8 | c.1240T>C p.W414R | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53730460; called by muse, mutect2, varscan2
- KEAP1 | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50318396; called by muse, mutect2
- KIF2B | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as rs771563360, COSV52132622; called by muse, mutect2, varscan2
- KRTAP13-3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61879701; called by muse, mutect2, varscan2
- LEMD3 | c.2093A>G p.H698R | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs929953790, COSV57651651; called by muse, mutect2
- LGI3 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60443782; called by muse, mutect2, varscan2
- MAGEA4 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV52342159; called by muse, mutect2
- MAGEL2 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV58567866; called by muse, mutect2, varscan2
- MARCHF11 | c.948T>G p.N316K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60130980; called by muse, mutect2, varscan2
- MAT1A | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV64746217; called by muse, mutect2, varscan2
- MERTK | c.191T>A p.M64K | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV54931789; called by muse, mutect2, varscan2
- MMP16 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 7/144 reads (5%) | catalogued as COSV54174094; called by muse, mutect2
- MYH4 | c.3007C>T p.L1003F | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55121270; called by muse, mutect2, varscan2
- NALCN | c.4030C>G p.L1344V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV51930065, COSV51946871; called by muse, mutect2, varscan2
- NALCN | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV51946892; called by muse, mutect2, varscan2
- NELL1 | c.269T>C p.L90S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.399); catalogued as COSV54286136; called by muse, mutect2, varscan2
- NEMF | c.3218T>G p.V1073G | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV53587730; called by muse, mutect2, varscan2
- NLRP12 | c.2136T>A p.N712K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.864); catalogued as COSV60750053; called by muse, mutect2
- NMNAT3 | c.337G>A p.G113S (on ENST00000296202 / NM_001320512.1; = p.G76S on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV56157225; called by muse, mutect2, varscan2
- NOD2 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56052528; called by muse, mutect2
- NPLOC4 | c.185A>T p.K62I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV58617272; called by muse, mutect2, varscan2
- NRP1 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55170755; called by muse, mutect2
- NXF3 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs751182875, COSV67702555; called by muse, mutect2, varscan2
- OBSCN | c.21166T>C p.C7056R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV62683222; called by muse, mutect2
- OR2T11 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as COSV58186382; called by muse, mutect2
- OR4K15 | c.887C>T p.A296V (on ENST00000305051; = p.A272V on NM_001005486.1) | Missense Mutation (SNP) | VAF 7/209 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100521189; called by muse, mutect2
- OR7D4 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV58072010, COSV58072621; called by muse, mutect2, varscan2
- ORM2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52279963; called by muse, mutect2, varscan2
- OTOGL | c.5369T>A p.F1790Y (on ENST00000547103; = p.F1781Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV54019260; called by muse, mutect2, varscan2
- PALMD | c.1096A>C p.K366Q | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV54165407; called by muse, mutect2
- PCDH9 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 28/182 reads (15%) | catalogued as COSV60565800; called by muse, mutect2, varscan2
- PCDHA5 | c.2352+1G>A p.X784_splice | Splice Site (SNP) | VAF 12/132 reads (9%) | catalogued as rs1554129741, COSV65354003; called by muse, mutect2
- PDGFA | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV63279959; called by muse, mutect2, varscan2
- POGK | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs770518724, COSV63311230; called by muse, mutect2, varscan2
- POTEC | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV62803444; called by muse, mutect2, varscan2
- PPP1R12A | c.1824-1G>A p.X608_splice | Splice Site (SNP) | VAF 31/171 reads (18%) | catalogued as COSV54110695; called by muse, mutect2, varscan2
- PRR5L | c.437C>A p.P146Q | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61122360; called by muse, mutect2
- PTPRC | c.1199G>A p.C400Y | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV61415154; called by muse, mutect2
- RASD2 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53352928; called by muse, mutect2, varscan2
- RNF169 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1237352449, COSV55133666; called by muse, mutect2
- RYR3 | c.9797C>A p.P3266H (on ENST00000389232; = p.P3267H on NM_001036.6) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66798188; called by muse, mutect2
- SCN1A | c.4571C>T p.P1524L (on ENST00000303395 / NM_001202435.3; = p.P1513L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57672296, COSV57676393; called by muse, mutect2
- SIM2 | c.1181T>C p.F394S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV51770430; called by muse, mutect2, varscan2
- SLC5A10 | c.499T>G p.W167G | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58759770; called by muse, mutect2
- SPAG17 | c.4712A>T p.Y1571F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60462228; called by muse, mutect2
- SPAG8 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV52414629; called by muse, mutect2, varscan2
- SPATA4 | c.583T>G p.S195A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV54590699; called by muse, mutect2, varscan2
- SPRR2B | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs749709146, COSV58797254; called by muse, mutect2, varscan2
- SQLE | c.1247T>G p.L416R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56281657; called by muse, mutect2, varscan2
- SYNPO2 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61113619; called by muse, mutect2, varscan2
- TAF1D | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.24); catalogued as COSV58681085; called by muse, mutect2, varscan2
- TAGAP | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57852456; called by muse, mutect2, varscan2
- THBS3 | c.1913A>T p.N638I | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64250086; called by muse, mutect2
- TMEFF1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs769712998, COSV58494990; called by muse, mutect2, varscan2
- TXK | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.055); catalogued as COSV51917225; called by muse, mutect2, varscan2
- UCP3 | c.280A>T p.I94F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58368699; called by muse, mutect2
- ZDBF2 | c.5792G>T p.G1931V | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV65627699, COSV65629764; called by muse, mutect2, varscan2
- ZFP82 | c.1152T>G p.H384Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67565783; called by muse, mutect2
- ZMYND12 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV65333714; called by muse, mutect2, varscan2
- ZNF33A | c.2213A>T p.H738L (on ENST00000458705 / NM_006974.3; = p.H739L on NM_006954.2) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56726261; called by muse, mutect2, varscan2
- ZNF485 | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62424750; called by muse, mutect2, varscan2
- ZNF638 | c.2705A>G p.E902G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV52491060; called by muse, mutect2
- ZNF646 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56216166; called by muse, mutect2, varscan2
- ZNF716 | c.444T>A p.C148* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as rs202240678, COSV101348543, COSV70781703; called by muse, mutect2, varscan2
- CHAMP1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2
- CNOT4 | c.86del p.F29Sfs*50 | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.4060C>T p.P1354S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNLT1 | c.313A>T p.I105F | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- EGFR | c.1061_1080del p.T354Kfs*17 | Frame Shift Del (DEL) | VAF 12/148 reads (8%) | called by mutect2, pindel
- FBXO31 | c.728_732+18del p.X243_splice | Splice Site (DEL) | VAF 18/174 reads (10%) | called by mutect2, pindel
- IGFBP5 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2
- NALCN | c.4243_4287del p.T1415_S1429del | In Frame Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel
- PHLPP1 | c.3983A>T p.E1328V | Missense Mutation (SNP) | VAF 6/151 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLCG1 | c.3362A>G p.Y1121C | Missense Mutation (SNP) | VAF 6/155 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2
- WNK4 | c.2158-1_2164del p.X720_splice | Splice Site (DEL) | VAF 15/165 reads (9%) | called by mutect2, pindel
- ABCB11 | c.3036C>T p.L1012= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV55585805; called by muse, mutect2, varscan2
- ASNSD1 | c.645G>T p.L215= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53624124; called by muse, mutect2, varscan2
- ATXN2L | c.2466A>G p.P822= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV57373751; called by muse, mutect2, varscan2
- CIC | c.4377A>G p.P1459= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1032540294, COSV50608885; called by muse, mutect2, varscan2
- COX6A1 | c.327A>G p.E109= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as COSV56663916; called by muse, mutect2, varscan2
- CROCC2 | c.3078C>T p.G1026= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs1054852169, COSV69132356; called by muse, mutect2, varscan2
- HDAC9 | c.1272G>A p.L424= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV67777515; called by muse, mutect2, varscan2
- HFM1 | c.2601A>G p.L867= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV54031065; called by muse, mutect2
- HSD17B7 | c.6A>G p.R2= | Silent (SNP) | VAF 71/567 reads (13%) | catalogued as COSV54418941; called by muse, mutect2, varscan2
- KIR3DL3 | c.864A>G p.G288= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- LRRC15 | c.66C>T p.Y22= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV61650646; called by muse, mutect2
- MARK1 | c.1854G>A p.Q618= | Silent (SNP) | VAF 12/233 reads (5%) | catalogued as COSV65068870; called by muse, mutect2
- MIER1 | c.648T>C p.P216= (on ENST00000355356 / NM_001077701.3; = p.P233= on NM_020948.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV62530891; called by muse, mutect2
- MUC16 | c.27717C>G p.S9239= | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as COSV67477219; called by muse, mutect2
- MYOM1 | c.1551G>A p.K517= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs745600639, COSV55295129; called by muse, mutect2, varscan2
- NDUFV2 | c.216A>G p.E72= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV59187613; called by muse, mutect2, varscan2
- NEK10 | c.711A>C p.A237= | Silent (SNP) | VAF 14/364 reads (4%) | catalogued as COSV100412421; called by muse, mutect2
- NKAIN2 | c.339A>T p.P113= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV63672802; called by muse, mutect2
- NUBPL | c.132C>T p.T44= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55270990; called by muse, mutect2, varscan2
- PCDHB5 | c.1614G>A p.P538= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV50657271, COSV99167804; called by muse, mutect2, varscan2
- PIK3R4 | c.2979A>G p.K993= | Silent (SNP) | VAF 12/352 reads (3%) | catalogued as COSV63240421; called by muse, mutect2
- SIAE | c.870T>C p.N290= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs947925798, COSV55014932; called by muse, mutect2, varscan2
- SPAG9 | c.3792G>T p.T1264= (on ENST00000262013 / NM_001130528.3; = p.T1250= on NM_003971.6) | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as rs112947211, COSV56238474; called by muse, mutect2, varscan2
- UBE2K | c.558A>G p.K186= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV54691288; called by muse, mutect2
- AKAP9 | c.11758+60dup | Intron (INS) | VAF 18/110 reads (16%) | called by mutect2, varscan2
- APOBEC3F | c.-31A>G | 5'UTR (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100415304; called by muse, varscan2
- CACNA1C | c.1217+391T>C | Intron (SNP) | VAF 17/157 reads (11%) | catalogued as COSV59739857; called by muse, mutect2
- CHRM3 | c.*2742G>T | 3'UTR (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- CTBP1 | chr4:1250907 A>G | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as rs1374183995; called by muse, mutect2
- FBXL21P | n.1368C>T | RNA (SNP) | VAF 6/158 reads (4%) | catalogued as COSV99778476; called by muse, mutect2
- GPC1 | c.167-8247A>C | Intron (SNP) | VAF 24/276 reads (9%) | catalogued as COSV50864241; called by muse, mutect2
- POLR2F | c.453-7973G>C | Intron (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- PSIP1 | c.978-1271T>C | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as COSV101051028; called by muse, mutect2
- RASGRP3 | c.-8A>G | 5'UTR (SNP) | VAF 16/198 reads (8%) | catalogued as COSV101274940; called by muse, mutect2
- THSD4 | c.-80+15189T>A | Intron (SNP) | VAF 11/89 reads (12%) | catalogued as COSV62498860; called by muse, mutect2, varscan2
